CPTAC case C3N-00440 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cfc3dba9-b0bd-498c-b8fc-33b80a7af835

Demographics
Sex at birth: male; Race: white; Year of birth: 1962; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Papillary renal cell carcinoma: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 53.7 years (19,619 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Residual disease: R1; Last known disease status: Tumor free; Days to last known disease status: 1,702 days (4.7 years); Progression or recurrence: no; Days to last follow up: 1,702 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.7 cm; Margin status: Involved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 365 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 732 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 1,118 days (3.1 years); Disease response: With Tumor.
- Days to follow up: 1,579 days (4.3 years); Disease response: Tumor Free.
- Days to follow up: 1,579 days (4.3 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 704 days (1.9 years).
- Days to follow up: 1,702 days (4.7 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 66 kg; Height: 175 cm; BMI: 21.55.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 52.5; Cigarettes per day: 30; Tobacco smoking onset year: 1980; Tobacco smoking quit year: 2015; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 35; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00440-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 281 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00440-22: Section location: Upper pole; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-00440-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
